Gene-level copy-number profile of tumor specimen TCGA-K4-A6FZ-01A from TCGA case TCGA-K4-A6FZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,686 days).
Specimen TCGA-K4-A6FZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9bd20a3c-9632-464e-9147-fe9e348aa596.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A6FZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2996085e-a77d-4a24-bf48-b68e9de46cf3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 16,421; copy number 3: 18,676; copy number 4: 17,482; copy number 5: 5,166; copy number 6: 1,606; copy number 7: 34; copy number 9: 32; copy number 11: 35; copy number 12: 67; copy number 13: 41; copy number 14: 85; copy number 18: 37; copy number 19: 72; copy number 22: 24; copy number 23: 10; copy number 24: 12; copy number 26: 9; copy number 30: 10; copy number 31: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A6FZ-01A-11D-A31K-01): tumor purity 0.33, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 424 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,943,626–60,038,586, 89 genes, copy number 14–19 (broad region; genes not listed).
- chr4:71,062,667–72,569,221, 9 genes, copy number 26 (within-gene range 2–26): SLC4A4, AC096713.1, LDHAL6EP, GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1.
- chr6:9,124,221–16,761,491, 118 genes, copy number 12–23 (within-gene range 7–23) (broad region; genes not listed).
- chr6:17,393,505–20,500,276, 45 genes, copy number 18–22 (within-gene range 7–22): CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA.
- chr7:5,823,160–8,004,053, 65 genes, copy number 9–11 (within-gene range 3–11) (broad region; genes not listed).
- chr7:9,850,924–9,985,895, 2 genes, copy number 9: AC006363.1, AC010991.1.
- chr11:57,917,297–59,058,659, 53 genes, copy number 13–24: OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4.
- chr22:20,917,407–21,451,463, 43 genes, copy number 14: CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, FAM246A, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
